Somatic mutation profile of tumor specimen C3N-02141-04 (aliquot CPT0118460006) from CPTAC case C3N-02141, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.4 years (26,460 days).
Specimen C3N-02141-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1c9ebd4-04b9-4e0d-8f76-b2674985be05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02141-31 (Blood Derived Normal), aliquot CPT0119690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cde2061f-bc53-4e2e-a3eb-f8510c56c50e

The open-access MAF lists 55 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, 3'UTR 2, RNA 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.981T>G p.Y327* | Nonsense Mutation (SNP) | VAF 79/362 reads (22%) | catalogued as rs879254077, COSV52678878, COSV52914365, COSV52993701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as rs1037978740, COSV65560937; called by muse, mutect2
- ADGRB3 | c.1162C>A p.H388N | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV65387851; called by muse, mutect2
- AKAP4 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 135/416 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV62075047; called by muse, mutect2, varscan2
- BBS9 | c.2269C>G p.L757V (on ENST00000242067 / NM_001348036.1; = p.L717V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/487 reads (5%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.74); catalogued as COSV54167564, COSV54171808; called by muse, mutect2
- BCAN | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100228318; called by muse, mutect2
- COL25A1 | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs751717158, COSV67650641; called by muse, mutect2
- CPA2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs749226338, COSV55981266; called by muse, mutect2
- FRMPD1 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 32/203 reads (16%) | catalogued as rs572307245, COSV63383660; called by muse, mutect2, varscan2
- MOXD1 | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV60943172; called by muse, mutect2
- NLGN1 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64322430; called by muse, mutect2
- POLR3E | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs375146644; called by muse, mutect2
- SLC8A1 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as COSV60493351; called by muse, mutect2
- TDRD9 | c.3574C>T p.H1192Y | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as rs1274862985; called by muse, mutect2
- WAS | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 65/646 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as CM155286; called by muse, mutect2, varscan2
- ZNF48 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs573433521, COSV100198003, COSV60783190; called by muse, mutect2
- ZNF721 | c.251C>G p.S84* (on ENST00000338977; = p.S96* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 7/133 reads (5%) | catalogued as rs1339355700; called by muse, mutect2
- ZNF747 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV99411384; called by muse, mutect2
- ABCB1 | c.2897A>G p.H966R | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- APOB | c.5274C>G p.N1758K | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.16); called by muse, mutect2
- DNAH6 | c.3274G>T p.A1092S | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- LAMP5 | c.722T>G p.L241W | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MAFA | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- MAPKAPK2 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED23 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); called by muse, mutect2
- NDRG2 | c.626G>A p.G209E (on ENST00000298687 / NM_001354570.1; = p.G195E on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- NEUROD2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 109/568 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PANK2 | c.1162G>T p.V388L (on ENST00000316562 / NM_153638.3; = p.V97L on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- PPP2R5A | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PSME4 | c.2590C>G p.H864D | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- SVIL | c.3907G>C p.D1303H (on ENST00000355867 / NM_021738.3; = p.D877H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- VWA5B2 | c.1563G>C p.E521D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WNK4 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 20/666 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ZNF445 | c.2257C>T p.Q753* | Nonsense Mutation (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- ZNF616 | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- ZNF771 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- AOC1 | c.777C>T p.D259= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as rs1171294662; called by muse, mutect2, varscan2
- FBXW12 | c.252G>A p.P84= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs764943929; called by muse, mutect2
- ITIH5 | c.807C>T p.S269= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- MTUS2 | c.2364A>C p.A788= | Silent (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- NTN1 | c.1761G>C p.R587= | Silent (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2
- OR10Z1 | c.351C>A p.A117= | Silent (SNP) | VAF 19/358 reads (5%) | called by muse, mutect2
- PHACTR3 | c.666G>A p.E222= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- SFTPB | c.369C>A p.V123= | Silent (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- STARD3 | c.936G>A p.K312= | Silent (SNP) | VAF 146/895 reads (16%) | catalogued as rs1221478420; called by muse, mutect2, varscan2
- STUB1 | c.840C>G p.L280= | Silent (SNP) | VAF 13/399 reads (3%) | catalogued as COSV50196498; called by muse, mutect2
- VSTM2A | c.207G>A p.P69= | Silent (SNP) | VAF 12/328 reads (4%) | catalogued as rs1430722325; called by muse, mutect2
- WIPF3 | c.891C>T p.P297= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- ZNF564 | c.153C>T p.S51= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, varscan2
- MIR1269A | n.45A>T | RNA (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- OPRM1 | c.1165-8247G>C | Intron (SNP) | VAF 21/145 reads (14%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*70G>A | 3'UTR (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- RBBP5 | c.*32T>A | 3'UTR (SNP) | VAF 16/254 reads (6%) | catalogued as COSV99196773; called by muse, mutect2
- SNORD116-2 | n.75T>G | RNA (SNP) | VAF 20/208 reads (10%) | catalogued as rs768364480; called by muse, mutect2
- TSPAN18 | c.-10-2543C>T | Intron (SNP) | VAF 10/184 reads (5%) | catalogued as rs1564985336; called by muse, mutect2
